TCGA case TCGA-HT-8113 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western - St Joes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9e621541-d603-4d2d-b86e-2834d3b9f9a5

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 49.8 years (18,173 days); Year of diagnosis: 2006; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 900 days (2.5 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 34 days; Days to treatment end: 75 days; Treatment dose: 5,400 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 34 days; Days to treatment end: 74 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 159 days; Days to treatment end: 331 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.

Follow-up (2 entries)
- Days to follow up: 102 days; Karnofsky performance status: 90.
- Days to follow up: 900 days (2.5 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Asthma; Risk factors: Asthma.
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Seizure.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HT-8113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 0.9; Shortest dimension: 0.6.
  Slide TCGA-HT-8113-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-HT-8113-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-HT-8113-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HT-8113-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: Tumor free; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: Yes; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: Yes; Family history brain tumor: No.
- Drug treatment 1: Pharmaceutical therapy drug name: temodar.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 900 days; disease-specific survival: no event (censored), 900 days; disease-free interval: no event (censored), 900 days; progression-free interval: no event (censored), 900 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HT-8113-01A-11D-2391-01): tumor purity 0.34, ploidy 1.94, whole-genome doublings 0.
